Surgical pathology report (de-identified scan), TCGA case TCGA-UD-AABZ, project TCGA-MESO (Mesothelioma), tissue source site  University of Western Australia, specimen TCGA-UD-AABZ-01A (Primary Tumor).

[page 1 of 2]
Printed

DOB:

Sex: M

Date of Service:

CLINICAL HISTORY:

? Mesothelioma ? Mucinous adenocarcinoma ? Lymphoma.

MACROSCOPIC:

1. Left chest wall: Nodular piece of solid grey-white tissue measuring 25mm x 20mm x 10mm. Slightly shiny cut surface (FS, A-D, lr).
2. Left lingula: A wedge shaped section of lung tissue measuring 60mm x 20mm x 10mm. A staple margin is seen at one edge. The pleural surface shows a diffuse firm area of white thickening measuring 60mm x 10mm. The cut surface shows the lung parenchyma to be replaced by firm white tissue

FROZEN SECTION REPORT:

1. **INVASIVE MALIGNANCY.** Provisional diagnosis mesothelioma vs adenocarcinoma. Await paraffin and IPOX for definite diagnosis.
Pathologist:

MICROSCOPIC:

1. Paraffin sections confirm an infiltrating malignant epithelioid neoplasm with luminal formation. There are ragged nests and infiltrating glandular type structures present with some focal areas of necrosis lying within a fibroblastic stroma. Some areas show a sheet-like growth pattern and large nested areas of growth also seen.

Page 1 of 3

Normal File
Notes Required
Patient Notified
Patient Will Call
Make Appointment
Collect Prescription
On Correlation Treatment
Check with Doctor

The tumour appears predominantly infiltrative however there is also some surface atypical proliferation with papillary pattern also present.

2. Sections show infiltrating malignant tumour with overall similar appearance to that described in specimen 1. The tumour involves the pleural surface and has breached the visceral pleural and extends into the underlying pulmonary parenchyma. Growth is on a broad front. Focal surface overlying fibrin exudation seen. There is also extension in small vascular spaces along the septae. Focally there is a visceral pleural atypical papillary proliferation of mesothelial cells. Special stains of infiltrating tumour show mucin stains are negative without definite intracytoplasmic neutral mucin positivity. Immunoperoxidase stains show infiltrating tumour CALRETININ positive, TTF-1 negative, CAM 5.2 positive, CK 7 positive, CK20 patchy weak to moderate positivity, EMA positive with cytoplasmic and rim positivity, AE 1/3 positive, PSA negative, CD15 negative, CEA negative, CK5/6 patchy moderate positivity.

Page 2 of 3

Normal File
Notes Required
Patient Notified
Patient Will Call
Make Appointment
Collect Prescription
On Correlation Treatment
Check with Doctor

M

ICD-O-3

Mesothelioma, epithelioid malignant 9052/3

Site: Pleura NOS C38.4

9/29/14

[page 2 of 2]
Printed

M

DOB:

Sex: M

- 3 -

CONCLUSION:

1. & 2. Left chest wall and left lingula: **MALIGNANT MESOTHELIOMA**
(nodular and diffuse growth pattern).

Pathologist:

Page 3 of 3

M

Normal
File

Notes
Required

Patient
Notified

Patient
Will Call

Make
Appointment

Collect
Prescription

On Correct
Treatment

Check with
Doctor

HPV A Discrepancy		
Tumor Malignancy History		

Source: NCI Genomic Data Commons file 60240246-b840-4607-879a-e9a8ea631258 (TCGA-UD-AABZ.FA7A0AF7-06C4-4F15-B3B6-8B9E39D526B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).